Somatic mutation profile of tumor specimen C3L-03629-02 (aliquot CPT0198810034) from CPTAC case C3L-03629, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 75.3 years (27,489 days).
Specimen C3L-03629-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ed1e8bc-ed3c-4e20-a1f3-d3db90d0696f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03629-31 (Blood Derived Normal), aliquot CPT0198840002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cdfc5c95-1fb3-4890-b53f-07539da41789

The open-access MAF lists 43 somatic variants for this specimen: 30 protein-altering or splice-affecting, 6 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 6, Nonsense Mutation 6, Intron 3, 3'UTR 2, 5'UTR 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 20/233 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2
- SMAD4 | c.1333C>T p.R445* | Nonsense Mutation (SNP) | VAF 29/354 reads (8%) | hotspot (GDC flag); catalogued as rs377767360, CM000742, COSV61685033; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.375+1G>T p.X125_splice | Splice Site (SNP) | VAF 8/186 reads (4%) | hotspot (GDC flag); catalogued as CS951538, COSV52663569, COSV52668477, COSV52702628; called by muse, mutect2
- ADAMTSL1 | c.2807G>A p.R936H | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as rs779204168, COSV65892972; called by muse, mutect2
- ADD2 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as rs150703767; called by muse, mutect2
- ADGRD1 | c.1780G>A p.V594M | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs189007948; called by muse, mutect2, varscan2
- AMELY | c.538C>T p.R180W (on ENST00000383036 / NM_001364814.1; = p.R166W on NM_001143.1) | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs779825282; called by muse, mutect2, varscan2
- ASTN1 | c.2315C>A p.P772H | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56074236; called by muse, mutect2
- BRINP1 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 42/540 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs148052034, COSV56309641; called by muse, mutect2
- CCDC154 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 28/278 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.03); catalogued as rs780545865; called by muse, mutect2
- CSMD2 | c.6862G>A p.A2288T | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as COSV53879842; called by muse, mutect2
- ITGAX | c.3086G>A p.R1029Q | Missense Mutation (SNP) | VAF 25/262 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.157); catalogued as rs777767407, COSV51652001, COSV99192076; called by muse, varscan2
- MORC2 | c.463C>T p.R155W (on ENST00000397641 / NM_001303256.3; = p.R93W on NM_014941.3) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as rs775518683, COSV53202933; called by mutect2, varscan2
- NRP1 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs760427841, COSV55160346; called by muse, mutect2, varscan2
- OR10J5 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 18/271 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs142763637; called by muse, mutect2
- TMCC2 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 36/414 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.848); catalogued as rs780957575; called by muse, mutect2
- ADAM15 | c.1951C>G p.L651V | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ADAM8 | c.1388G>T p.G463V | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ALDH1A1 | c.752G>A p.G251D | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- APOB | c.2877C>G p.N959K | Missense Mutation (SNP) | VAF 28/437 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); called by muse, mutect2
- DENND4A | c.4687C>T p.R1563* | Nonsense Mutation (SNP) | VAF 10/74 reads (14%) | called by muse, mutect2
- FGF8 | c.518G>T p.R173L (on ENST00000344255 / NM_033164.4; = p.R155L on NM_006119.6) | Missense Mutation (SNP) | VAF 48/576 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- HSPA4L | c.2022T>A p.Y674* | Nonsense Mutation (SNP) | VAF 12/126 reads (10%) | called by muse, mutect2
- PLEKHA6 | c.508C>T p.Q170* | Nonsense Mutation (SNP) | VAF 45/375 reads (12%) | called by muse, mutect2, varscan2
- PTPRF | c.4360G>T p.E1454* | Nonsense Mutation (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- RIPK1 | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.036); called by muse, mutect2
- SPATA31A7 | c.260G>A p.C87Y | Missense Mutation (SNP) | VAF 32/866 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.37); called by muse, mutect2
- TANC2 | c.607A>G p.K203E | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.53); called by muse, mutect2
- TMEM106B | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2, varscan2
- TMEM273 | c.206C>A p.S69Y | Missense Mutation (SNP) | VAF 30/361 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.407); called by muse, mutect2
- DCAF4L1 | c.345C>T p.Y115= | Silent (SNP) | VAF 15/146 reads (10%) | catalogued as rs765518456, COSV60787146; called by muse, mutect2
- INAVA | c.1398C>T p.H466= | Silent (SNP) | VAF 33/152 reads (22%) | catalogued as rs746757443; called by muse, mutect2, varscan2
- MUC6 | c.6630C>T p.A2210= | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as COSV70132414; called by muse, mutect2
- NPAS3 | c.1767G>A p.A589= (on ENST00000356141 / NM_001164749.2; = p.A557= on NM_022123.3) | Silent (SNP) | VAF 28/424 reads (7%) | catalogued as rs759470482; called by muse, mutect2
- PGD | c.186C>T p.V62= | Silent (SNP) | VAF 16/259 reads (6%) | called by muse, mutect2
- PHKB | c.1218A>G p.V406= | Silent (SNP) | VAF 14/128 reads (11%) | called by muse, mutect2, varscan2
- CLPS | c.84+373C>A | Intron (SNP) | VAF 8/125 reads (6%) | called by muse, mutect2
- CXCL12 | c.*440G>A | 3'UTR (SNP) | VAF 16/168 reads (10%) | called by muse, mutect2
- CYTH4 | c.434+764G>C | Intron (SNP) | VAF 18/247 reads (7%) | called by muse, mutect2
- ERBB4 | c.-27C>T | 5'UTR (SNP) | VAF 36/584 reads (6%) | catalogued as rs371640361; called by muse, mutect2
- HACE1 | c.1075-19dup | Intron (INS) | VAF 11/99 reads (11%) | called by mutect2, pindel
- LINC02381 | n.327C>T | RNA (SNP) | VAF 19/98 reads (19%) | called by muse, mutect2, varscan2
- PLEKHM1 | c.*1107C>T | 3'UTR (SNP) | VAF 38/436 reads (9%) | called by muse, mutect2
